Gene-level copy-number profile of tumor specimen ALCH-B28N-TTP1-A from ALCHEMIST case ALCH-B28N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,194 days).
Specimen ALCH-B28N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fa281383-59dc-45cd-98dd-530ed709a340.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B28N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/ff23d5b8-0014-47de-a90d-052ac3f73217

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 217; copy number 1: 10,321; copy number 2: 44,918; copy number 3: 3,433; copy number 4: 17.

Homozygous deletions (total copy number 0; autosomes only): 164 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,319,434, 7 genes: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P.
- chr2:90,359,809–91,580,863, 4 genes: AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr2:131,464,900–131,521,573, 4 genes: MZT2A, TUBA3D, MIR4784, SMPD4BP.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:62,275,361–63,060,084, 4 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3.
- chr8:43,539,137–46,028,892, 6 genes: AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr10:38,601,418–42,367,974, 14 genes: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,409,042–54,725,816, 12 genes: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr13:111,316,184–111,344,249, 1 gene: TEX29.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:14,407,668–14,418,908, 1 gene: AC040173.1.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:24,162,370–24,163,425, 1 gene: AC073534.1.
- chr19:38,211,006–38,229,714, 1 gene: DPF1.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.
- chr22:17,734,138–19,150,292, 72 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,814. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
